Somatic mutation profile of tumor specimen TCGA-B5-A11X-01A (aliquot TCGA-B5-A11X-01A-11D-A10M-09) from TCGA case TCGA-B5-A11X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 66.3 years (24,217 days).
Specimen TCGA-B5-A11X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0fec065-3079-402d-9f0d-f95872658c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11X-10A (Blood Derived Normal), aliquot TCGA-B5-A11X-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58c23598-c863-4472-bbbd-fe8154606d05

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 2, Nonstop Mutation 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV55904673; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 37/154 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 43/206 reads (21%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABHD13 | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65534797; called by muse, mutect2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- ADD2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs370808317; called by muse, mutect2, varscan2
- APOB | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV51933727; called by muse, mutect2, varscan2
- ARID1A | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 92/326 reads (28%) | catalogued as COSV61376549; called by muse, mutect2, varscan2
- ATP13A2 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780992643, COSV58700065; called by muse, mutect2, varscan2
- ATP2B2 | c.1361T>C p.I454T (on ENST00000352432; = p.I420T on NM_001683.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59495272; called by muse, mutect2
- BAIAP3 | c.1023C>A p.H341Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV60979686; called by muse, mutect2, varscan2
- CAMK2B | c.819C>T p.C273= | Splice Region (SNP) | VAF 63/269 reads (23%) | catalogued as rs774396408, COSV51659888; called by muse, mutect2, varscan2
- CHD3 | c.4024C>T p.R1342W | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57874597; called by muse, mutect2, varscan2
- CNKSR2 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV54254968; called by muse, mutect2, varscan2
- DCAF8L1 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 45/192 reads (23%) | catalogued as rs775242035, COSV71595250; called by muse, mutect2, varscan2
- EPHB1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67659906; called by muse, mutect2, varscan2
- FAM47B | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV61453529; called by muse, mutect2, varscan2
- GHITM | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1216928773, COSV64538435; called by muse, mutect2, varscan2
- H4C4 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV61591032; called by muse, mutect2, varscan2
- HSP90AB1 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771117200, COSV62334320; called by muse, mutect2, varscan2
- IGHM | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); catalogued as rs782379311; called by muse, mutect2, varscan2
- INO80D | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756238431, COSV68958756; called by muse, mutect2, varscan2
- KRT6B | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV52883345; called by muse, mutect2, varscan2
- LUC7L2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54925184; called by muse, mutect2, varscan2
- MED12 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs875989806, COSV61337658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED13 | c.1492G>T p.V498L | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.133); catalogued as rs776058960, COSV67263265; called by muse, mutect2, varscan2
- MUC5B | c.4475C>T p.T1492M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs567562795, COSV71591729; called by muse, mutect2, varscan2
- NEDD4L | c.2407A>G p.N803D (on ENST00000400345 / NM_001144967.3; = p.N783D on NM_015277.6) | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV56843847; called by muse, mutect2, varscan2
- NFASC | c.545C>T p.P182L (on ENST00000339876 / NM_001378329.1; = p.P176L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV58364329; called by muse, mutect2
- NREP | c.205T>A p.*69Kext*2 | Nonstop Mutation (SNP) | VAF 30/257 reads (12%) | catalogued as COSV57405086; called by muse, mutect2, varscan2
- OBSCN | c.7724C>T p.A2575V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.214); catalogued as COSV52769386; called by muse, mutect2, varscan2
- OR8J1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 25/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs181729175, COSV57317950; called by muse, mutect2
- OSBPL8 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53881722; called by muse, mutect2
- PEX1 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV50397537; called by muse, mutect2, varscan2
- PROX1 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs1253863076, COSV54778508; called by muse, mutect2, varscan2
- PTEN | c.23del p.I8Tfs*16 | Frame Shift Del (DEL) | VAF 63/299 reads (21%) | catalogued as COSV104426438, COSV64295859, COSV64306624; called by mutect2, pindel, varscan2
- RALYL | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV72820118; called by muse, mutect2, varscan2
- RLIM | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV60326195; called by muse, mutect2, varscan2
- RTL9 | c.2306C>A p.T769K | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV71825518; called by muse, mutect2, varscan2
- SARDH | c.1020+2T>C p.X340_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as COSV64096552; called by muse, mutect2, varscan2
- SCARB2 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668645; called by muse, mutect2, varscan2
- SHPRH | c.207T>G p.D69E | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV51608506; called by muse, mutect2, varscan2
- SIN3A | c.3197T>G p.L1066R | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV64582675; called by muse, mutect2, varscan2
- SLC13A5 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866581532, COSV53422903; called by muse, mutect2, varscan2
- SMC1A | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs782175064, COSV59128996; called by muse, mutect2, varscan2
- SULF1 | c.1565G>C p.R522P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV52680069; called by muse, mutect2, varscan2
- TG | c.5386C>A p.Q1796K | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as CM102020, COSV55073948; called by muse, mutect2, varscan2
- TMEM255B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs771068834, COSV64703540, COSV64704708; called by muse, mutect2, varscan2
- TNS1 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50700518; called by muse, mutect2, varscan2
- TP53INP2 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66351214; called by muse, mutect2
- TTC24 | c.1404dup p.E469Rfs*34 | Frame Shift Ins (INS) | VAF 34/137 reads (25%) | catalogued as rs765522798; called by mutect2, pindel, varscan2
- TTC7A | c.348G>A p.S116= | Splice Region (SNP) | VAF 30/111 reads (27%) | catalogued as rs779808838, COSV55410600; called by muse, mutect2, varscan2
- ARID1A | c.6705_6708del p.A2237Cfs*29 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- CTCF | c.54del p.G19Efs*43 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- COL6A2 | c.1236C>A p.G412= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56003795, COSV56007592; called by muse, mutect2, varscan2
- DDX54 | c.318G>A p.P106= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as rs752301417, COSV58373193; called by muse, mutect2, varscan2
- EEF2 | c.735G>A p.G245= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV58579264; called by muse, mutect2, varscan2
- GLB1L3 | c.270C>T p.F90= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs750188980, COSV66280916; called by muse, mutect2, varscan2
- HKDC1 | c.532C>A p.R178= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs748281031, COSV63576839, COSV63578198; called by muse, mutect2, varscan2
- KRTAP5-1 | c.690C>T p.C230= | Silent (SNP) | VAF 43/239 reads (18%) | catalogued as rs769088333, COSV66298954; called by muse, mutect2, varscan2
- LDOC1 | c.102G>T p.V34= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV65159238; called by muse, mutect2, varscan2
- PCARE | c.1776G>A p.T592= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs201520631, COSV59054616; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB2 | c.1998C>T p.D666= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs782464820, COSV50564095; called by muse, mutect2, varscan2
- PCM1 | c.4878C>T p.R1626= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV59586440; called by muse, mutect2, varscan2
- SLC16A1 | c.486C>G p.A162= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs17852383, COSV63709190; called by mutect2, varscan2
- SRGAP1 | c.861G>A p.A287= | Silent (SNP) | VAF 53/181 reads (29%) | catalogued as rs137909926; called by muse, mutect2, varscan2
- STARD8 | c.1083C>A p.L361= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV52925573; called by muse, mutect2
- TSHZ3 | c.1422C>T p.V474= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as rs774032101, COSV53670143; called by muse, mutect2, varscan2
- AKAP7 | c.851-28486G>T | Intron (SNP) | VAF 21/320 reads (7%) | catalogued as COSV53834751; called by muse, mutect2
- ZNF658B | n.2438G>A | RNA (SNP) | VAF 34/192 reads (18%) | catalogued as rs1168582984; called by muse, mutect2, varscan2
